Somatic mutation profile of tumor specimen TCGA-BP-4994-01A (aliquot TCGA-BP-4994-01A-01D-1462-08) from TCGA case TCGA-BP-4994, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.6 years (19,946 days).
Specimen TCGA-BP-4994-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddc780f5-1ec9-45cf-804a-00aa5b2083f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4994-11A (Solid Tissue Normal), aliquot TCGA-BP-4994-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/250e3e3a-16fa-4022-ae6c-f68d11bd1f46

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 9 silent.
By variant classification: Silent 9, Missense Mutation 6, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.1073G>C p.C358S | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67796853; called by muse, mutect2
- KCNN1 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs944927086, COSV55836946; called by muse, mutect2, varscan2
- LILRB2 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV58743524; called by muse, mutect2, varscan2
- PCDHA10 | c.856C>G p.P286A | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as COSV56477521, COSV56550520; called by muse, mutect2, varscan2
- RUFY3 | c.656A>T p.D219V | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56911236; called by muse, mutect2
- SLK | c.3322-2A>G p.X1108_splice | Splice Site (SNP) | VAF 12/67 reads (18%) | catalogued as COSV59823750; called by muse, mutect2, varscan2
- ZKSCAN2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | catalogued as COSV100047933; called by muse, mutect2
- ZNF766 | c.258C>G p.I86M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV63009069; called by muse, mutect2
- CHD6 | c.3454_3455del p.K1152Efs*63 | Frame Shift Del (DEL) | VAF 45/289 reads (16%) | called by mutect2, pindel, varscan2
- CLCC1 | c.1042-3_1042-2del p.X348_splice (on ENST00000356970 / NM_001377464.1; = p.X298_splice on NM_015127.5) | Splice Site (DEL) | VAF 10/48 reads (21%) | called by mutect2, varscan2
- DOP1A | c.3008del p.H1003Lfs*42 | Frame Shift Del (DEL) | VAF 42/188 reads (22%) | called by mutect2, pindel, varscan2
- CACNA1B | c.717C>A p.I239= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV53112589, COSV99496139; called by mutect2, varscan2
- FCRLB | c.552T>C p.A184= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV61059297; called by muse, mutect2
- MRPL9 | c.225G>A p.R75= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs1191786282, COSV58617315; called by muse, mutect2, varscan2
- NIN | c.1242G>T p.R414= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV55380099; called by muse, mutect2, varscan2
- PCDHAC1 | c.2568C>A p.S856= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV53836736; called by muse, mutect2, varscan2
- PIP4K2C | c.1107C>T p.F369= | Silent (SNP) | VAF 17/240 reads (7%) | catalogued as COSV61605677; called by muse, mutect2
- PLCZ1 | c.720T>A p.S240= | Silent (SNP) | VAF 19/305 reads (6%) | catalogued as COSV56848854; called by muse, mutect2
- SYT8 | c.849C>A p.V283= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV53288601; called by muse, mutect2
- TBCD | c.1266G>A p.A422= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs754912961, COSV62797615; called by muse, mutect2, varscan2
